Somatic mutation profile of tumor specimen TCGA-BP-5007-01A (aliquot TCGA-BP-5007-01A-01D-1462-08) from TCGA case TCGA-BP-5007, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 46.0 years (16,793 days).
Specimen TCGA-BP-5007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6f1e150-5ea0-4379-b3f8-16a2efd6ace4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5007-11A (Solid Tissue Normal), aliquot TCGA-BP-5007-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1001fd5c-be2a-44a3-8a25-44329fb3f944

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Del 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B15 | c.355A>C p.K119Q | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV71152187; called by muse, mutect2, varscan2
- DAGLA | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs771001941, COSV57197210; called by muse, mutect2, varscan2
- DOLPP1 | c.689A>C p.Q230P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV59910594; called by muse, mutect2, varscan2
- DOT1L | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as COSV67110568; called by muse, mutect2, varscan2
- GPC5 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65596965; called by muse, mutect2, varscan2
- GPN2 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64652240; called by muse, mutect2, varscan2
- HERC1 | c.8734A>G p.I2912V | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71248487; called by muse, mutect2
- HOXC8 | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs1182128101, COSV50001933; called by muse, mutect2, varscan2
- IFT140 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV68490028; called by muse, mutect2, varscan2
- MS4A12 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs146116909; called by muse, mutect2, varscan2
- MYSM1 | c.2475A>T p.E825D | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.156); catalogued as COSV68977676; called by muse, mutect2, varscan2
- PARD6B | c.757_758del p.N253* | Frame Shift Del (DEL) | VAF 69/222 reads (31%) | catalogued as COSV65404655; called by mutect2, pindel, varscan2
- RUFY2 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 35/167 reads (21%) | catalogued as COSV56259893; called by muse, mutect2, varscan2
- SCAF4 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV54588589; called by muse, mutect2, varscan2
- SLC17A4 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 100/317 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV64956515; called by muse, mutect2, varscan2
- VEZT | c.87A>T p.E29D | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54140689; called by muse, mutect2, varscan2
- WDR72 | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.994); catalogued as COSV64748855; called by muse, mutect2, varscan2
- ZNF100 | c.1519C>A p.H507N | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59748340; called by muse, mutect2, varscan2
- ZNF623 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71697230; called by muse, mutect2
- IFIT3 | c.1370del p.F457Sfs*33 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- SIN3B | c.1658del p.P553Rfs*19 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- SUPT7L | c.459_460del p.C154Sfs*18 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- ZSCAN16 | c.220del p.C74Afs*8 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | called by mutect2, varscan2
- DCHS1 | c.6060C>T p.I2020= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV55037642; called by muse, mutect2
- FAAH | c.654A>T p.S218= | Silent (SNP) | VAF 15/267 reads (6%) | catalogued as COSV54544502; called by muse, mutect2
- HAPLN1 | c.375C>A p.V125= | Silent (SNP) | VAF 84/324 reads (26%) | catalogued as COSV57149053; called by muse, mutect2, varscan2
- KIF19 | c.639C>A p.A213= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs564644989, COSV63429728; called by muse, mutect2, varscan2
- LMAN1 | c.48G>A p.L16= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV51825920, COSV51827459; called by muse, mutect2, varscan2
- TBC1D10B | c.834G>A p.G278= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV69505196; called by muse, mutect2
- TOGARAM1 | c.4651C>T p.L1551= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV63892838; called by muse, mutect2, varscan2
